Somatic mutation profile of tumor specimen MP2PRT-PATGSB-TMP1-A (aliquot MP2PRT-PATGSB-TMP1-A-1-0-D-A81Y-36) from MP2PRT case MP2PRT-PATGSB, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.8 years (660 days).
Specimen MP2PRT-PATGSB-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 11ec843b-7f12-4f53-9ed3-d018a4a0b285.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATGSB-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATGSB-NB1-A-1-0-D-A81Y-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9222b18f-2139-402c-9929-b95f3ddcd574

The open-access MAF lists 6 somatic variants for this specimen: 3 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 3, Silent 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 140/428 reads (33%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PDZRN4 | c.19C>T p.R7C | Missense Mutation (SNP) | VAF 19/460 reads (4%) | SIFT deleterious, low confidence (0); catalogued as rs867360162; called by muse, mutect2
- TMEM229A | c.801G>C p.Q267H | Missense Mutation (SNP) | VAF 21/505 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.007); called by muse, mutect2
- ANKRD55 | c.1005G>T p.R335= | Silent (SNP) | VAF 112/301 reads (37%) | called by muse, mutect2
- HCN1 | c.189C>T p.G63= | Silent (SNP) | VAF 203/614 reads (33%) | called by muse, varscan2
- TMEM121 | c.297G>A p.A99= | Silent (SNP) | VAF 30/947 reads (3%) | catalogued as rs782122861; called by muse, mutect2
